Somatic mutation profile of tumor specimen MMRF_2411_1_BM_CD138pos (aliquot MMRF_2411_1_BM_CD138pos_T1_KHS5U_L11081) from MMRF case MMRF_2411, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.8 years (20,739 days).
Specimen MMRF_2411_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6345ac54-014e-406b-bf0b-d836b3207d15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2411_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2411_1_PB_Whole_C2_KHS5U_L11082; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2489e798-31c5-49a4-b5ec-c28281a655b5

The open-access MAF lists 241 somatic variants for this specimen: 92 protein-altering or splice-affecting, 30 silent, 119 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, 3'UTR 62, Intron 33, Silent 30, 5'UTR 10, Nonsense Mutation 9, Splice Site 6, RNA 5, 3'Flank 5, 5'Flank 4, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59510417; called by muse, mutect2, varscan2
- ACTRT2 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753602379; called by muse, mutect2, varscan2
- ADRB1 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1262544913, COSV65167781; called by muse, mutect2, varscan2
- ARHGEF16 | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV65681278; called by muse, mutect2, varscan2
- ARMC1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); catalogued as rs766048093, COSV52533344; called by muse, mutect2, varscan2
- BLOC1S6 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 69/357 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV55035264, COSV55035355; called by muse, mutect2, varscan2
- CDC42BPA | c.5179C>A p.R1727S (on ENST00000334218 / NM_001366019.2; = p.R1714S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); catalogued as COSV100506311; called by muse, mutect2, varscan2
- CDH9 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 108/320 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776212558, COSV50264628; called by muse, varscan2
- CLK2 | c.496G>A p.V166I (on ENST00000368361 / NM_001294339.2; = p.V165I on NM_003993.4) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs533711087; called by muse, mutect2, varscan2
- DMD | c.10697G>A p.R3566H | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58897842; called by muse, mutect2, varscan2
- ERICH3 | c.1851G>C p.R617S | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100445423; called by muse, mutect2, varscan2
- FAM47A | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 102/103 reads (99%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.659); catalogued as COSV60500448; called by muse, mutect2, varscan2
- FREM1 | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs563740380, COSV66520934; called by muse, mutect2, varscan2
- FSD1 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.303); catalogued as rs766976177; called by muse, mutect2, varscan2
- GALNT5 | c.1934G>T p.G645V | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV52035604; called by muse, mutect2
- GAS8 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs138104460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGLV3-25 | c.62A>C p.Y21S | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs773446767; called by muse, mutect2
- KIAA0100 | c.1537C>G p.L513V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV101197175; called by muse, mutect2
- LRRC66 | c.805A>T p.I269F | Missense Mutation (SNP) | VAF 31/317 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs947729903, COSV58637390; called by muse, mutect2
- MUC17 | c.12769T>G p.Y4257D | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV60303147; called by muse, mutect2, varscan2
- NDUFB4 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 31/255 reads (12%) | catalogued as rs757896006; called by muse, mutect2, varscan2
- NOTCH2 | c.5110C>T p.R1704C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs750129192, COSV56708417; called by muse, mutect2, varscan2
- OR52M1 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1391892608; called by muse, mutect2, varscan2
- OR7A17 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1358613719; called by muse, mutect2, varscan2
- PTPN21 | c.3115T>A p.Y1039N | Missense Mutation (SNP) | VAF 56/385 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1349780550; called by muse, mutect2, varscan2
- PTPRF | c.4472G>A p.R1491H | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375234489; called by muse, mutect2, varscan2
- RC3H1 | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.92); PolyPhen benign (0.225); catalogued as rs1375714662; called by muse, mutect2, varscan2
- RYR3 | c.3709T>C p.F1237L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs1475925000; called by muse, mutect2
- SPEG | c.9689C>T p.T3230M | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201629381, COSV56663848; called by muse, mutect2, varscan2
- SPRY2 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 53/103 reads (51%) | catalogued as COSV101001680, COSV101001696; called by muse, mutect2, varscan2
- THNSL1 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150117447; called by muse, mutect2, varscan2
- TRIM72 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284100831; called by muse, mutect2
- ZNF491 | c.836C>G p.A279G | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.193); catalogued as rs568130014; called by muse, mutect2, varscan2
- ZNF749 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs778079013, COSV100494423; called by muse, mutect2
- ABCA7 | c.5629G>C p.A1877P | Missense Mutation (SNP) | VAF 81/349 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- ABCA8 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- AGFG2 | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALDH1A2 | c.1460A>T p.K487M | Missense Mutation (SNP) | VAF 22/523 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ALG10B | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALG10B | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMOTL1 | c.857A>C p.K286T | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ANKRD39 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 89/181 reads (49%) | called by muse, mutect2, varscan2
- ARRDC2 | c.341+1_341+28del p.X114_splice | Splice Site (DEL) | VAF 14/176 reads (8%) | called by mutect2, pindel
- CACNA2D3 | c.449A>T p.K150M | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CCDC141 | c.4325+1G>T p.X1442_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- CDH2 | c.2210-1G>T p.X737_splice | Splice Site (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- CFAP97D1 | c.407A>T p.Y136F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- CNNM1 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- CUBN | c.7702G>T p.A2568S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ESD | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 111/219 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FES | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 240/373 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- FPGT | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT2 | c.1301A>G p.Y434C | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR3B | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- IRF2BPL | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | called by muse, varscan2
- KCTD12 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- KIAA2026 | c.379C>A p.R127S | Missense Mutation (SNP) | VAF 81/148 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRRC24 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- MRPL46 | c.653_679del p.P218_N226del | In Frame Del (DEL) | VAF 38/332 reads (11%) | called by mutect2, pindel
- MYLK | c.848C>A p.S283* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- NEB | c.16334A>T p.Y5445F | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NPTXR | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.829); called by muse, mutect2
- OR10J3 | c.426T>A p.C142* | Nonsense Mutation (SNP) | VAF 57/127 reads (45%) | called by muse, mutect2, varscan2
- OR5AC2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 12/116 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OTOG | c.7562C>T p.P2521L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.389); called by muse, mutect2
- OTOG | c.7945_7971+10del p.X2649_splice | Splice Site (DEL) | VAF 48/258 reads (19%) | called by mutect2, pindel
- PCDH10 | c.2570T>C p.V857A | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2
- PCDHA12 | c.592A>T p.K198* | Nonsense Mutation (SNP) | VAF 12/225 reads (5%) | called by muse, mutect2
- PCDHGA6 | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PCOLCE | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- PIAS1 | c.934+5G>A | Splice Region (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2
- POM121L2 | c.2593T>A p.F865I | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PRUNE2 | c.7886A>C p.Q2629P | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PTPN6 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- RTP5 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.026); called by muse, mutect2
- SESN3 | c.78+1G>A p.X26_splice | Splice Site (SNP) | VAF 55/200 reads (28%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.1762A>G p.T588A | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.247); called by muse, varscan2
- SOX11 | c.650T>A p.V217D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- SPTBN4 | c.5084+5G>T | Splice Region (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- SSTR2 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 26/265 reads (10%) | called by muse, mutect2
- TBC1D9B | c.1416+1del p.X472_splice | Splice Site (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- TCERG1 | c.2828A>C p.E943A | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TENM1 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TET2 | c.4424del p.A1475Efs*96 | Frame Shift Del (DEL) | VAF 73/168 reads (43%) | called by mutect2, pindel, varscan2
- TMTC4 | c.2020T>A p.L674I (on ENST00000376234 / NM_001350577.2; = p.L693I on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.068); called by muse, mutect2
- TPD52 | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, varscan2
- TRIM2 | c.1557C>G p.F519L (on ENST00000437508; = p.F546L on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TRIM65 | c.1487C>T p.T496I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TSGA10 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 76/136 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTC3 | c.1101T>A p.Y367* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- ZNF589 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB11 | c.2901G>A p.L967= | Silent (SNP) | VAF 24/179 reads (13%) | catalogued as COSV55591645; called by muse, mutect2, varscan2
- ABCB11 | c.2196G>A p.V732= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- AHNAK | c.5553G>A p.K1851= | Silent (SNP) | VAF 117/371 reads (32%) | catalogued as rs1364444996; called by muse, mutect2, varscan2
- ATP10A | c.4059T>G p.P1353= | Silent (SNP) | VAF 14/124 reads (11%) | called by mutect2, varscan2
- BCL11B | c.687C>T p.P229= (on ENST00000357195 / NM_001282237.2; = p.P158= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as rs1439311592; called by muse, mutect2, varscan2
- BCLAF1 | c.1134G>A p.Q378= | Silent (SNP) | VAF 32/48 reads (67%) | called by muse, mutect2, varscan2
- C4orf54 | c.2475C>T p.H825= | Silent (SNP) | VAF 101/211 reads (48%) | catalogued as rs769377732; called by muse, mutect2, varscan2
- CTC1 | c.2656C>T p.L886= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2
- CUBN | c.6894G>A p.G2298= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- DDIT4 | c.321G>A p.A107= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as rs1437275653; called by muse, mutect2
- DPYSL4 | c.732G>A p.K244= | Silent (SNP) | VAF 74/136 reads (54%) | called by muse, mutect2, varscan2
- GPC2 | c.1248T>C p.S416= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- IGLV3-25 | c.282T>C p.S94= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as rs750483958; called by muse, varscan2
- IGLV3-27 | c.136C>T p.L46= | Silent (SNP) | VAF 96/205 reads (47%) | catalogued as rs759925988; called by muse, mutect2, varscan2
- KIF27 | c.1879C>T p.L627= | Silent (SNP) | VAF 30/696 reads (4%) | called by muse, mutect2
- MAPK8IP2 | c.2025G>C p.R675= | Silent (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- MBOAT1 | c.762G>A p.L254= | Silent (SNP) | VAF 62/106 reads (58%) | called by muse, mutect2, varscan2
- OSBPL5 | c.843C>A p.V281= | Silent (SNP) | VAF 44/151 reads (29%) | catalogued as COSV99720417; called by muse, mutect2, varscan2
- PAK3 | c.198G>A p.E66= | Silent (SNP) | VAF 63/68 reads (93%) | called by muse, mutect2, varscan2
- PCARE | c.2865G>A p.R955= | Silent (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- PDE1C | c.189G>A p.G63= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV101275980, COSV68807336; called by muse, mutect2, varscan2
- PIK3AP1 | c.75G>A p.Q25= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as rs202093664; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3147C>T p.F1049= | Silent (SNP) | VAF 84/187 reads (45%) | catalogued as rs543082155; called by muse, mutect2, varscan2
- RYR3 | c.9174A>G p.A3058= (on ENST00000389232; = p.A3059= on NM_001036.6) | Silent (SNP) | VAF 46/214 reads (21%) | called by muse, mutect2, varscan2
- SERPINA6 | c.897G>A p.L299= | Silent (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- SETD3 | c.636C>T p.N212= | Silent (SNP) | VAF 58/179 reads (32%) | catalogued as rs769192938; called by muse, mutect2, varscan2
- SLC40A1 | c.411C>T p.I137= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- TMEM132A | c.249C>A p.L83= | Silent (SNP) | VAF 67/271 reads (25%) | catalogued as COSV99137556; called by muse, mutect2, varscan2
- TUBA4A | c.372G>A p.K124= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as rs746442903; called by muse, mutect2, varscan2
- UNC13C | c.6408A>T p.S2136= | Silent (SNP) | VAF 36/607 reads (6%) | called by muse, mutect2
- ABCA8 | c.2916+88T>C | Intron (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- ACTB | c.-27-116A>G | Intron (SNP) | VAF 56/169 reads (33%) | catalogued as rs1416974291; called by muse, mutect2, varscan2
- ADPGK | c.-92A>G | 5'UTR (SNP) | VAF 27/217 reads (12%) | catalogued as rs1002353224; called by muse, mutect2, varscan2
- AP000311.1 | c.-134G>A | 5'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- AR | c.1769-5126G>C | Intron (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.1006-16C>T | Intron (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- BAK1 | c.*517C>T | 3'UTR (SNP) | VAF 21/140 reads (15%) | catalogued as rs1327708875, COSV100645832; called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576434 A>T | 5'Flank (SNP) | VAF 9/63 reads (14%) | called by mutect2, varscan2
- BMP6 | c.*1220_*1270del | 3'UTR (DEL) | VAF 34/150 reads (23%) | called by mutect2, pindel
- C3orf70 | c.*367G>A | 3'UTR (SNP) | VAF 71/237 reads (30%) | catalogued as rs1031912810; called by muse, mutect2, varscan2
- CCDC178 | c.*540del | 3'UTR (DEL) | VAF 17/37 reads (46%) | called by mutect2, pindel, varscan2
- CCL5 | c.*670C>T | 3'UTR (SNP) | VAF 48/75 reads (64%) | catalogued as rs375632597; called by muse, mutect2, varscan2
- CDH11 | c.*2831G>T | 3'UTR (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- CDK10 | c.538+16G>C | Intron (SNP) | VAF 42/71 reads (59%) | called by muse, mutect2, varscan2
- CEP104 | c.566+1789G>A | Intron (SNP) | VAF 42/333 reads (13%) | called by muse, mutect2, varscan2
- CERS6 | c.*3814G>C | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- CNR2 | c.*2613G>A | 3'UTR (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- CNTN5 | c.*2243A>T | 3'UTR (SNP) | VAF 38/56 reads (68%) | catalogued as rs1306038654; called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+11493T>C | Intron (SNP) | VAF 58/208 reads (28%) | catalogued as rs1231292073; called by muse, mutect2, varscan2
- DCAF12 | c.-248C>T | 5'UTR (SNP) | VAF 6/126 reads (5%) | catalogued as rs1263809431; called by muse, mutect2
- DCLK1 | c.*156C>G | 3'UTR (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- DCLK1 | c.941-1191G>C | Intron (SNP) | VAF 15/31 reads (48%) | called by mutect2, varscan2
- DIO1 | c.*467A>G | 3'UTR (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- DKK2 | c.*1888G>A | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- DNAJC19 | c.*513G>C | 3'UTR (SNP) | VAF 21/73 reads (29%) | called by muse, varscan2
- DPP8 | c.-172C>A | 5'UTR (SNP) | VAF 82/520 reads (16%) | called by muse, mutect2, varscan2
- EFCAB11 | c.410+8046C>G | Intron (SNP) | VAF 46/159 reads (29%) | called by muse, mutect2, varscan2
- EPYC | c.*154T>C | 3'UTR (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- FOXJ3 | c.1454-74del | Intron (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- GABRG1 | c.*2691G>A | 3'UTR (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- GAREM2 | c.254-1306A>G | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- GCSAM | c.*2573G>C | 3'UTR (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- GNG13 | c.*495_*528del | 3'UTR (DEL) | VAF 28/60 reads (47%) | called by muse*, mutect2, varscan2*
- HAGHL | c.499-26G>C | Intron (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- HAUS7 | c.384+818T>G | Intron (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- HIPK2 | c.*5520del | 3'UTR (DEL) | VAF 22/106 reads (21%) | catalogued as rs1173063482; called by mutect2, varscan2
- HLA-B | c.619+84C>T | Intron (SNP) | VAF 43/127 reads (34%) | called by muse, mutect2, varscan2
- HMCN2 | c.14587+12C>A | Intron (SNP) | VAF 56/161 reads (35%) | catalogued as rs1404900423; called by muse, mutect2, varscan2
- HMGB4 | c.-428A>T | 5'UTR (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2, varscan2
- HNF4A | c.*1484A>T | 3'UTR (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- HOXA9 | c.*1083T>A | 3'UTR (SNP) | VAF 15/218 reads (7%) | called by muse, mutect2
- HS6ST1P1 | n.1143C>T | RNA (SNP) | VAF 17/24 reads (71%) | catalogued as rs1312677125; called by muse, mutect2, varscan2
- IFIT2 | c.*1344C>A | 3'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- IMMT | c.-70G>A | 5'UTR (SNP) | VAF 8/30 reads (27%) | catalogued as rs1045382265; called by muse, mutect2, varscan2
- KALRN | c.4929+8508T>C | Intron (SNP) | VAF 71/273 reads (26%) | catalogued as rs768694908; called by muse, mutect2, varscan2
- KALRN | c.4929+8509G>T | Intron (SNP) | VAF 71/271 reads (26%) | called by muse, mutect2, varscan2
- KIF14 | c.*1262C>T | 3'UTR (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- KLK6 | c.198-44C>T | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- LCP2 | c.*1615C>T | 3'UTR (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- LHX5 | c.*757C>T | 3'UTR (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- LINC02206 | n.369T>G | RNA (SNP) | VAF 53/884 reads (6%) | called by muse, mutect2
- LINC02724 | n.107C>G | RNA (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- LRIG3 | c.*39C>A | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- LRRCC1 | c.105-47G>A | Intron (SNP) | VAF 13/26 reads (50%) | catalogued as rs1214854092; called by muse, mutect2, varscan2
- LRRIQ1 | c.5016+110C>A | Intron (SNP) | VAF 48/77 reads (62%) | called by muse, mutect2, varscan2
- LTBR | c.*321C>T | 3'UTR (SNP) | VAF 16/159 reads (10%) | catalogued as rs1490940536; called by muse, mutect2, varscan2
- MAPK9 | c.*1982A>T | 3'UTR (SNP) | VAF 43/117 reads (37%) | called by muse, mutect2, varscan2
- MCF2L | chr13:113097217 T>C | 3'Flank (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- METTL8 | chr2:171434727 G>A | 5'Flank (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2
- MFRP | chr11:119341400 C>T | 3'Flank (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2, varscan2
- MIR5195 | n.91C>G | RNA (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- MKS1 | c.*571A>G | 3'UTR (SNP) | VAF 56/388 reads (14%) | called by muse, mutect2, varscan2
- NAT8L | c.*2716G>T | 3'UTR (SNP) | VAF 84/175 reads (48%) | called by muse, varscan2
- NDUFV1 | chr11:67604879 A>T | 5'Flank (SNP) | VAF 63/229 reads (28%) | called by muse, mutect2, varscan2
- NEUROD1 | c.*451G>C | 3'UTR (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- NXPH3 | c.*628C>G | 3'UTR (SNP) | VAF 27/205 reads (13%) | called by muse, mutect2, varscan2
- OSM | c.*64G>C | 3'UTR (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- PAXBP1 | c.*29T>C | 3'UTR (SNP) | VAF 182/303 reads (60%) | called by muse, mutect2, varscan2
- PDE10A | c.*4152G>T | 3'UTR (SNP) | VAF 29/31 reads (94%) | called by muse, mutect2, varscan2
- PDE6A | c.*1411T>C | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- PGAP2 | c.418+39C>T | Intron (SNP) | VAF 24/353 reads (7%) | called by muse, mutect2
- PHOX2B | c.*363G>A | 3'UTR (SNP) | VAF 32/223 reads (14%) | called by muse, mutect2, varscan2
- PID1 | chr2:229024972 C>T | 3'Flank (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- PLAU | c.*150A>G | 3'UTR (SNP) | VAF 44/114 reads (39%) | called by muse, mutect2
- PNPLA5 | c.*895G>T | 3'UTR (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- PON3 | c.695+110T>G | Intron (SNP) | VAF 10/35 reads (29%) | called by mutect2, varscan2
- PPP1R14C | c.*932C>T | 3'UTR (SNP) | VAF 33/36 reads (92%) | catalogued as rs1208767740; called by muse, mutect2, varscan2
- PPP2R3A | c.-22A>C | 5'UTR (SNP) | VAF 69/200 reads (35%) | called by muse, mutect2, varscan2
- PPP4R4 | c.*438G>T | 3'UTR (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- PPRC1 | c.4550+10_4550+16del | Intron (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- PRIMA1 | c.-15G>T | 5'UTR (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*5345C>A | 3'UTR (SNP) | VAF 6/68 reads (9%) | catalogued as rs569005918; called by muse, mutect2
- PTPRG | c.2560-42G>T | Intron (SNP) | VAF 108/162 reads (67%) | called by muse, mutect2, varscan2
- PYGO1 | c.*1609A>C | 3'UTR (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- RALBP1 | c.*748G>T | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- RAMP1 | c.*16C>A | 3'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- RPE65 | c.*409C>A | 3'UTR (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- RUNX1 | c.*3990T>A | 3'UTR (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- SCUBE2 | c.256+99T>C | Intron (SNP) | VAF 52/203 reads (26%) | called by muse, varscan2
- SLC18A3 | c.*184A>G | 3'UTR (SNP) | VAF 20/247 reads (8%) | called by muse, mutect2
- SLC22A10 | c.*306G>A | 3'UTR (SNP) | VAF 20/74 reads (27%) | called by muse, varscan2
- SLC3A1 | c.766-308C>T | Intron (SNP) | VAF 27/272 reads (10%) | catalogued as rs1306538573; called by muse, mutect2
- SPA17 | c.-27-539C>T | Intron (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- SPATA8 | n.956T>A | RNA (SNP) | VAF 52/678 reads (8%) | catalogued as COSV100138986; called by muse, mutect2
- ST6GALNAC6 | c.*6_*18del | 3'UTR (DEL) | VAF 47/222 reads (21%) | called by mutect2, pindel, varscan2
- SUB1 | c.*611T>C | 3'UTR (SNP) | VAF 43/129 reads (33%) | catalogued as rs1410326119; called by muse, mutect2, varscan2
- SYBU | chr8:109647262 A>G | 5'Flank (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- TBC1D4 | c.-225C>T | 5'UTR (SNP) | VAF 42/89 reads (47%) | catalogued as rs1010261840; called by muse, mutect2, varscan2
- TECR | c.800-23_800-6del | Intron (DEL) | VAF 22/227 reads (10%) | called by mutect2, pindel
- TEKT4 | c.499-466G>A | Intron (SNP) | VAF 18/30 reads (60%) | catalogued as rs1396369093; called by muse, mutect2
- TMEM233 | c.-27G>A | 5'UTR (SNP) | VAF 37/84 reads (44%) | catalogued as rs1401583509, COSV70311641; called by muse, mutect2, varscan2
- TNFRSF14 | c.305-272C>T | Intron (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- TRAK1 | c.*207G>A | 3'UTR (SNP) | VAF 17/107 reads (16%) | catalogued as rs560821417; called by muse, mutect2, varscan2
- UHMK1 | c.*3818G>A | 3'UTR (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- UNC80 | c.*510C>T | 3'UTR (SNP) | VAF 13/144 reads (9%) | called by muse, mutect2
- VAPA | c.*3798A>G | 3'UTR (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- VGLL3 | c.*2394C>T | 3'UTR (SNP) | VAF 12/114 reads (11%) | catalogued as rs965511325; called by muse, mutect2
- WNK2 | chr9:93320438 del G | 3'Flank (DEL) | VAF 28/210 reads (13%) | called by mutect2, pindel*, varscan2*
- WRAP73 | c.922+11C>T | Intron (SNP) | VAF 90/220 reads (41%) | called by muse, mutect2, varscan2
- XKR4 | c.*1411C>A | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- XPR1 | c.*383G>A | 3'UTR (SNP) | VAF 20/40 reads (50%) | catalogued as rs898502767; called by muse, mutect2, varscan2
- YIF1A | c.642-10C>T | Intron (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- YTHDC1 | c.*976_*984del | 3'UTR (DEL) | VAF 8/63 reads (13%) | called by mutect2, varscan2
- ZAP70 | c.402+39T>A | Intron (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- ZAR1L | chr13:32303762 A>C | 3'Flank (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- ZMYM3 | c.*1110C>A | 3'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- ZNF695 | c.*585A>C | 3'UTR (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- ZNF829 | c.*431C>T | 3'UTR (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- ZSWIM5 | c.*87G>T | 3'UTR (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
